Somatic mutation profile of tumor specimen TCGA-C4-A0F0-01A (aliquot TCGA-C4-A0F0-01A-12D-A10S-08) from TCGA case TCGA-C4-A0F0, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 60.4 years (22,068 days).
Specimen TCGA-C4-A0F0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 150728e7-aeef-40dd-bad9-fe799d104015.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C4-A0F0-10A (Blood Derived Normal), aliquot TCGA-C4-A0F0-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38e55484-a1ef-4534-95f1-1f4a49c66d9b

The open-access MAF lists 108 somatic variants for this specimen: 83 protein-altering or splice-affecting, 24 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 24, Frame Shift Del 9, Nonsense Mutation 5, Splice Site 4, In Frame Del 3, Translation Start Site 2, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1215+1G>T p.X405_splice | Splice Site (SNP) | VAF 69/124 reads (56%) | hotspot (GDC flag); catalogued as CS890133, CS982341, COSV57294684, COSV57294939, COSV57306748; called by muse, mutect2, varscan2
- ACP3 | c.303G>A p.Q101= | Splice Region (SNP) | VAF 9/30 reads (30%) | catalogued as COSV60485928; called by muse, mutect2, varscan2
- ACVRL1 | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.65); catalogued as rs369146413; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADCY8 | c.2303C>G p.P768R | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV53901251, COSV53906580, COSV99650702; called by muse, mutect2, varscan2
- ADGRF2 | c.1421A>T p.Q474L (on ENST00000296862 / NM_001368115.2; = p.Q406L on NM_153839.7) | Missense Mutation (SNP) | VAF 72/140 reads (51%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.524); catalogued as COSV57288221; called by muse, mutect2, varscan2
- ANK1 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 69/394 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV55880939; called by muse, mutect2, varscan2
- ARHGAP39 | c.2408G>A p.R803H | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); catalogued as rs752652890, COSV52769840; called by muse, mutect2
- ASB3 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54857977; called by muse, mutect2, varscan2
- ATP10A | c.3976G>T p.A1326S | Missense Mutation (SNP) | VAF 53/104 reads (51%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV63517050; called by muse, mutect2, varscan2
- BMP4 | c.27G>T p.M9I | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV55415898; called by muse, mutect2, varscan2
- CACNA1F | c.23_25+15del p.X8_splice | Splice Site (DEL) | VAF 24/51 reads (47%) | catalogued as COSV59904369; called by mutect2, pindel, varscan2
- CAMTA1 | c.3759C>G p.F1253L | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV57899206; called by muse, mutect2, varscan2
- CAPRIN2 | c.2130G>T p.M710I | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV51832418; called by muse, mutect2, varscan2
- CARNMT1 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs200933121; called by muse, mutect2
- CD93 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); catalogued as rs1270079431, COSV55665003; called by muse, mutect2
- CDK20 | c.599G>T p.G200V (on ENST00000325303 / NM_001039803.3; = p.G179V on NM_012119.4) | Missense Mutation (SNP) | VAF 63/171 reads (37%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.589); catalogued as COSV57482612, COSV57483343; called by muse, mutect2, varscan2
- CLUAP1 | c.142C>G p.P48A | Missense Mutation (SNP) | VAF 88/141 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV58893569; called by muse, mutect2, varscan2
- CNTN1 | c.2729G>A p.R910K | Missense Mutation (SNP) | VAF 51/77 reads (66%) | SIFT tolerated (0.64); PolyPhen benign (0.009); catalogued as rs143121881; called by muse, mutect2, varscan2
- CREBBP | c.4307G>A p.S1436N | Missense Mutation (SNP) | VAF 34/44 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV52119405, COSV52136794; called by muse, mutect2, varscan2
- CSNK1E | c.411_412del p.L138Gfs*51 | Frame Shift Del (DEL) | VAF 66/150 reads (44%) | catalogued as COSV63290765; called by mutect2, pindel, varscan2
- DCC | c.3742G>A p.V1248M | Missense Mutation (SNP) | VAF 72/175 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs201242417, COSV101473359, COSV71429727; called by muse, mutect2, varscan2
- EMILIN3 | c.347T>A p.L116H | Missense Mutation (SNP) | VAF 72/221 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV60036119; called by muse, mutect2, varscan2
- FBXO22 | c.1060T>G p.L354V | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57617391; called by muse, mutect2, varscan2
- FBXW7 | c.963G>A p.W321* (on ENST00000281708 / NM_001349798.2; = p.W241* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 35/55 reads (64%) | catalogued as COSV55915376; called by muse, mutect2, varscan2
- FMO3 | c.1333C>T p.P445S | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs745366803, COSV63007137; called by muse, mutect2, varscan2
- FREM2 | c.23G>T p.G8V | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.402); catalogued as COSV54836942; called by muse, mutect2
- GCNT1 | c.1202A>C p.K401T | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65057664; called by muse, mutect2, varscan2
- GP2 | c.4C>G p.P2A | Missense Mutation (SNP) | VAF 76/111 reads (68%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV56893899; called by muse, mutect2, varscan2
- HCN1 | c.1546C>T p.Q516* | Nonsense Mutation (SNP) | VAF 10/134 reads (7%) | catalogued as COSV100299484; called by muse, mutect2
- IL10 | c.167_177del p.Q56Pfs*16 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as COSV65594513; called by mutect2, pindel
- INPP5F | c.944A>G p.H315R | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.044); catalogued as rs950147739, COSV62821230; called by muse, mutect2, varscan2
- INTU | c.2375C>T p.T792I | Missense Mutation (SNP) | VAF 51/82 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1281002301, COSV58871518; called by muse, mutect2, varscan2
- ITGA9 | c.2869G>C p.G957R | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.165); catalogued as COSV53241748; called by muse, varscan2
- KDM3B | c.4346G>T p.R1449M | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV58690547; called by muse, mutect2, varscan2
- KDM5B | c.2840G>A p.G947E | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as COSV52507434, COSV99349838; called by muse, mutect2, varscan2
- KRT32 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 51/213 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as rs865954221, COSV56786596; called by muse, mutect2, varscan2
- LMO7 | c.4480G>T p.E1494* (on ENST00000357063; = p.E1175* on NM_005358.5) | Nonsense Mutation (SNP) | VAF 30/118 reads (25%) | catalogued as COSV58542743; called by muse, mutect2, varscan2
- LRIG1 | c.3160T>C p.Y1054H | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1163429430, COSV56239759; called by muse, mutect2, varscan2
- MAP2K1 | c.704T>A p.L235H | Missense Mutation (SNP) | VAF 95/261 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61070585; called by muse, mutect2, varscan2
- MFSD12 | c.500C>T p.T167M | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs372325734; called by muse, mutect2, varscan2
- NFKBID | c.196T>A p.Y66N (on ENST00000396901; = p.Y218N on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV61728542; called by muse, mutect2, varscan2
- OR10C1 | c.704G>A p.R235H (on ENST00000622521; = p.R233H on NM_013941.3) | Missense Mutation (SNP) | VAF 39/393 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as rs771138562, COSV101010813, COSV65822160; called by muse, mutect2
- OR13G1 | c.772del p.R258Afs*14 | Frame Shift Del (DEL) | VAF 54/140 reads (39%) | catalogued as COSV62944488; called by mutect2, pindel, varscan2
- OR2AG2 | c.742G>A p.V248I | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58455089; called by muse, mutect2, varscan2
- OR2T1 | c.838C>T p.L280F | Missense Mutation (SNP) | VAF 60/277 reads (22%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.987); catalogued as COSV63541834; called by muse, mutect2, varscan2
- OR5D18 | c.115A>T p.T39S | Missense Mutation (SNP) | VAF 110/218 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.088); catalogued as COSV61737046; called by muse, mutect2
- OR6N1 | c.21C>A p.S7R | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as COSV58648310; called by muse, mutect2
- PADI4 | c.1871G>A p.G624D | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1347045567, COSV64923945; called by muse, mutect2, varscan2
- PCNT | c.2333C>G p.A778G | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV64027864; called by muse, mutect2
- PDE1C | c.560T>C p.F187S | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV58513112; called by muse, mutect2, varscan2
- RELN | c.3209T>C p.M1070T | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as rs1554389059, COSV59000550; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RNF133 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.155); catalogued as COSV57362282; called by muse, mutect2, varscan2
- SEMA3A | c.650A>T p.D217V | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54869869; called by muse, mutect2, varscan2
- SLC4A4 | c.2308G>A p.V770I (on ENST00000264485 / NM_001098484.3; = p.V726I on NM_003759.4) | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.8); PolyPhen benign (0.104); catalogued as rs150967020, COSV52623703; called by muse, mutect2, varscan2
- SON | c.5182A>G p.I1728V | Missense Mutation (SNP) | VAF 82/241 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as rs1237269717, COSV51656973; called by muse, mutect2, varscan2
- ST20 | c.58G>A p.V20I | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.094); catalogued as COSV51913706; called by muse, mutect2, varscan2
- STXBP5L | c.1478A>T p.K493I | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56512428; called by muse, mutect2, varscan2
- TLK2 | c.1558G>C p.E520Q (on ENST00000326270 / NM_001284333.2; = p.E498Q on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.199); catalogued as COSV58299816; called by muse, mutect2, varscan2
- TMEM123 | c.409C>T p.H137Y | Missense Mutation (SNP) | VAF 4060/4262 reads (95%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.827); catalogued as COSV63443946; called by mutect2, varscan2
- TTLL7 | c.1816C>T p.R606W | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs143330409; called by muse, mutect2, varscan2
- TTN | c.15404T>C p.F5135S (on ENST00000591111; = p.F4208S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/23 reads (48%) | PolyPhen probably damaging (0.997); catalogued as rs1439374405, COSV60041000; called by muse, mutect2, varscan2
- USP38 | c.1730G>A p.R577H | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.099); catalogued as rs753055918, COSV61024909; called by muse, mutect2, varscan2
- VPS33A | c.372_376del p.L125Gfs*42 | Frame Shift Del (DEL) | VAF 63/189 reads (33%) | catalogued as COSV57357043; called by pindel, varscan2
- ZKSCAN5 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.26); catalogued as COSV58742738; called by muse, mutect2, varscan2
- ZNF211 | c.965T>C p.F322S (on ENST00000347302 / NM_198855.4; = p.F335S on NM_006385.5) | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53741748; called by muse, mutect2, varscan2
- ZNF230 | c.285C>G p.I95M | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as COSV71273393; called by muse, mutect2, varscan2
- ABCA13 | c.13448_13455del p.I4483Kfs*22 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | called by mutect2, pindel, varscan2
- ATP5F1B | c.88C>G p.Q30E | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2
- AVPR1A | c.689_701delinsG p.V230_T234delinsG | In Frame Del (DEL) | VAF 50/113 reads (44%) | called by pindel, varscan2*
- CARNMT1 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.956); called by muse, mutect2
- COL7A1 | c.7930G>T p.G2644* | Nonsense Mutation (SNP) | VAF 59/214 reads (28%) | called by muse, mutect2, varscan2
- DSC3 | c.2306C>G p.S769* | Nonsense Mutation (SNP) | VAF 23/90 reads (26%) | called by muse, mutect2, varscan2
- FAM126B | c.1235del p.P412Qfs*6 | Frame Shift Del (DEL) | VAF 9/76 reads (12%) | called by mutect2, pindel, varscan2
- FLOT2 | c.856_889del p.V286Sfs*10 | Frame Shift Del (DEL) | VAF 20/101 reads (20%) | called by mutect2, pindel
- KCNK1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); called by muse, mutect2
- MMP9 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- OR52K1 | c.98del p.F33Sfs*10 | Frame Shift Del (DEL) | VAF 85/178 reads (48%) | called by mutect2, pindel, varscan2
- SLC2A13 | c.289T>G p.Y97D | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMTNL2 | c.1360_1362delinsAA p.Y454Kfs*64 (on ENST00000389313 / NM_001114974.2; = p.Y310Kfs*64 on NM_198501.3) | Frame Shift Del (DEL) | VAF 61/231 reads (26%) | called by pindel, varscan2*
- SULF1 | c.1062-3_1062-1delinsT p.X354_splice | Splice Site (DEL) | VAF 76/399 reads (19%) | called by pindel, varscan2*
- USP5 | c.2141_2173del p.G714_P724del (on ENST00000229268 / NM_001098536.2; = p.G691_P701del on NM_003481.3 and 2 other RefSeq transcripts) | In Frame Del (DEL) | VAF 28/226 reads (12%) | called by mutect2, pindel
- WASHC2A | c.1241_1243del p.X414_splice | Splice Site (DEL) | VAF 40/86 reads (47%) | called by mutect2, pindel, varscan2
- ZBTB10 | c.2244_2255del p.R748_C752delinsS (on ENST00000430430; = p.R724_C728delinsS on NM_023929.4) | In Frame Del (DEL) | VAF 7/40 reads (18%) | called by mutect2, pindel, varscan2
- ABCC9 | c.3168T>C p.T1056= | Silent (SNP) | VAF 57/133 reads (43%) | catalogued as COSV53970691; called by muse, mutect2, varscan2
- ABCD1 | c.1020C>T p.S340= | Silent (SNP) | VAF 17/136 reads (13%) | catalogued as rs781828983, COSV54384051; called by muse, mutect2, varscan2
- ADGRG7 | c.1101T>C p.F367= | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as rs1021489760, COSV56296387; called by muse, mutect2, varscan2
- AGTPBP1 | c.892C>T p.L298= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as COSV61271391; called by muse, mutect2, varscan2
- ANGEL1 | c.534A>G p.P178= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV51873149; called by muse, mutect2, varscan2
- BCOR | c.1461A>G p.L487= | Silent (SNP) | VAF 46/65 reads (71%) | catalogued as rs767700902, COSV60706615, COSV60707188; called by muse, mutect2, varscan2
- CCP110 | c.570C>G p.T190= | Silent (SNP) | VAF 140/207 reads (68%) | catalogued as COSV66816950; called by muse, mutect2, varscan2
- CD163 | c.12C>T p.L4= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV63130168, COSV63132022; called by muse, mutect2, varscan2
- COL4A4 | c.1563C>A p.G521= | Silent (SNP) | VAF 115/186 reads (62%) | catalogued as COSV61631959; called by muse, mutect2, varscan2
- DCC | c.753C>A p.A251= | Silent (SNP) | VAF 37/108 reads (34%) | catalogued as COSV59101068; called by muse, mutect2, varscan2
- FAM98C | c.15G>A p.K5= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV53038835; called by muse, mutect2, varscan2
- FBXO24 | c.426C>T p.T142= (on ENST00000241071 / NM_033506.3; = p.T180= on NM_012172.5) | Silent (SNP) | VAF 53/143 reads (37%) | catalogued as COSV53825812; called by muse, mutect2, varscan2
- FRMPD1 | c.4170C>T p.T1390= | Silent (SNP) | VAF 69/147 reads (47%) | catalogued as rs147765962; called by muse, mutect2, varscan2
- HYDIN | c.9939C>T p.A3313= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as rs553587582, COSV66863115; called by muse, mutect2, varscan2
- IGKV3D-11 | c.99G>A p.L33= | Silent (SNP) | VAF 14/114 reads (12%) | called by muse, mutect2, varscan2
- IGLV5-37 | c.204C>A p.L68= | Silent (SNP) | VAF 34/116 reads (29%) | catalogued as rs1049407742; called by muse, mutect2, varscan2
- LSM10 | c.216C>G p.L72= | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as COSV59872352; called by muse, mutect2, varscan2
- LZTS3 | c.180G>A p.G60= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs768427446, COSV61277740; called by muse, mutect2, varscan2
- MAP1B | c.5775C>G p.T1925= | Silent (SNP) | VAF 11/99 reads (11%) | catalogued as COSV57098540; called by muse, mutect2, varscan2
- PLXNB1 | c.4908C>T p.Y1636= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as rs959858225, COSV56489465; called by muse, mutect2, varscan2
- SLC5A4 | c.213C>T p.G71= | Silent (SNP) | VAF 52/90 reads (58%) | catalogued as rs751438943, COSV56670236; called by muse, mutect2, varscan2
- TMEM47 | c.270C>A p.A90= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as COSV52064561; called by muse, mutect2, varscan2
- USP47 | c.519C>T p.S173= (on ENST00000399455 / NM_001372095.1; = p.S85= on NM_017944.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 27/221 reads (12%) | catalogued as COSV60463528; called by muse, mutect2, varscan2
- ZNF714 | c.1434G>A p.E478= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV52511599; called by muse, mutect2, varscan2
- LHX9 | chr1:197912545 del C | 5'Flank (DEL) | VAF 69/210 reads (33%) | called by mutect2, pindel, varscan2
